Somatic mutation profile of tumor specimen TCGA-OR-A5L2-01A (aliquot TCGA-OR-A5L2-01A-11D-A30A-10) from TCGA case TCGA-OR-A5L2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 83.6 years (30,535 days).
Specimen TCGA-OR-A5L2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df2ca53-41e6-4ede-bda3-82f5ad55073b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L2-10A (Blood Derived Normal), aliquot TCGA-OR-A5L2-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdc1ae81-2c3f-40a8-aaef-3302c203bd1b

The open-access MAF lists 138 somatic variants for this specimen: 103 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 32, Nonsense Mutation 12, Intron 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52741167; called by muse, mutect2, varscan2
- ACSL1 | c.1403G>A p.C468Y | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs866671555; called by muse, mutect2, varscan2
- CACNA1I | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs373284314; called by mutect2, varscan2
- CCDC121 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV53114750; called by muse, mutect2, varscan2
- CCDC39 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1182604379, COSV56482150, COSV56483486; called by muse, mutect2, varscan2
- CD163L1 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs756556844; called by muse, mutect2, varscan2
- CD209 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs200282091; called by muse, mutect2, varscan2
- CDC42BPB | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1445044341; called by muse, mutect2
- CTR9 | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs372648972; called by muse, varscan2
- FLT4 | c.2560G>A p.G854S | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032227, CM078058; called by muse, mutect2
- GCN1 | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56105172, COSV56116103; called by muse, mutect2, varscan2
- HEATR1 | c.4822G>A p.V1608M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs935067724; called by muse, mutect2, varscan2
- KIF5A | c.3071C>G p.P1024R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.154); catalogued as COSV54052321; called by muse, mutect2, varscan2
- KRCC1 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61251091; called by muse, mutect2, varscan2
- LPAR2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs575876718, COSV99179055; called by muse, mutect2
- NOS2 | c.563T>A p.F188Y | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV100569988; called by muse, mutect2, varscan2
- PCDHGB7 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs754177868; called by muse, mutect2, varscan2
- PTPN6 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV59684096; called by muse, mutect2
- RASGRF2 | c.2470G>T p.A824S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV54128217; called by muse, mutect2
- RTP1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs926145867, COSV56617848; called by muse, mutect2, varscan2
- SPANXN3 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100980824; called by muse, varscan2
- SYCP3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs763365723; called by muse, mutect2, varscan2
- TBX4 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 55/158 reads (35%) | catalogued as rs749007884, COSV53610282; called by muse, mutect2, varscan2
- TCF7L2 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV60504153, COSV60507235; called by muse, mutect2, varscan2
- TEC | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67404233; called by muse, mutect2, varscan2
- TH | c.503G>A p.R168H (on ENST00000381178 / NM_199292.3; = p.R137H on NM_000360.4) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs768153273; called by muse, mutect2
- TOGARAM2 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs760340544, COSV65419595; called by muse, mutect2, varscan2
- TRIM39 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs745569249; called by muse, mutect2
- TTN | c.62062G>T p.A20688S (on ENST00000591111; = p.A13264S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | PolyPhen benign (0.072); catalogued as rs886055253; called by muse, mutect2, varscan2
- VPS35 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs747325352, COSV54480206; called by muse, mutect2, varscan2
- WFDC8 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.094); catalogued as COSV51489032; called by muse, mutect2, varscan2
- WFIKKN2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796276301; called by muse, mutect2, varscan2
- WHRN | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs774765831, COSV54330667; called by muse, mutect2, varscan2
- ZNF281 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54169096; called by muse, mutect2, varscan2
- AATF | c.519G>C p.E173D | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC11 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- ALKBH1 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID2 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARPP21 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 72/246 reads (29%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.305T>A p.I102N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BAAT | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- BLOC1S4 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- C16orf89 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.024); called by muse, mutect2
- C1orf158 | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- C22orf31 | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDH5 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CFAP58 | c.1728A>T p.E576D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHEK2 | c.680A>T p.N227I (on ENST00000382580 / NM_001005735.2; = p.N184I on NM_007194.4) | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.196); called by muse, mutect2
- CLIP1 | c.2933G>C p.S978T (on ENST00000620786 / NM_001247997.1; = p.S967T on NM_002956.2) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CORIN | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPED1 | c.1363A>T p.M455L | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CPSF3 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF2RB | c.1699C>G p.P567A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CUL9 | c.5515C>G p.P1839A | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60L | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAJA2 | c.175A>T p.N59Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DNAJB2 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- FGF23 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2
- FRAS1 | c.10449C>G p.I3483M | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GADD45G | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- GLRB | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- GPA33 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GRK4 | c.164G>C p.S55T (on ENST00000398052 / NM_182982.3; = p.S23T on NM_005307.3) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2
- HOMER2 | c.523C>G p.Q175E (on ENST00000304231 / NM_199330.3; = p.Q164E on NM_004839.4) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFIT1B | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- INTS3 | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- IRX4 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
- KLK11 | c.524T>C p.L175P (on ENST00000594768 / NM_144947.3; = p.L143P on NM_006853.3) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- LHX5 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- LIPN | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LY75 | c.3986C>A p.T1329N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEB4 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEE1 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 18/331 reads (5%) | called by muse, mutect2
- MAGEE1 | c.2556_2567del p.R853_A856del | In Frame Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- MAP3K1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MCF2L2 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MYOM2 | c.1921C>A p.L641M | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFYA | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NLRP4 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- NOS1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C16 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- PCARE | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- PCNX2 | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- PEG3 | c.2722G>T p.V908F | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.034); called by muse, mutect2
- PIN4 | c.358C>G p.Q120E (on ENST00000664196; = p.Q95E on NM_006223.4) | Missense Mutation (SNP) | VAF 79/400 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PLEKHH2 | c.3884T>A p.V1295D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- RASGRF1 | c.2988G>C p.E996D | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2
- RPRD2 | c.1742G>A p.S581N | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCNN1A | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- SERINC1 | c.760-26_763del p.X254_splice | Splice Site (DEL) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- SNW1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- SPEG | c.8692A>G p.T2898A | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRBD1 | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TBX21 | c.911C>G p.A304G | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNN | c.119T>A p.V40D | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TOM1L1 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNDC5 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- UHRF2 | c.711G>C p.L237F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- UHRF2 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- USP28 | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, varscan2
- VSIG2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- ABL1 | c.2496C>T p.H832= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- AL669918.1 | c.2247C>T p.H749= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- C4orf50 | c.648T>A p.G216= (on ENST00000324058; = p.G1448= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/153 reads (38%) | called by muse, mutect2, varscan2
- CCDC14 | c.1551G>A p.V517= (on ENST00000488653; = p.V469= on NM_022757.5) | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- CCNL2 | c.96G>T p.S32= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs985186202; called by muse, mutect2, varscan2
- CENPF | c.4752C>T p.L1584= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs200241672; called by muse, mutect2, varscan2
- COL22A1 | c.1611G>T p.L537= | Silent (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8184G>A p.L2728= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- ENTHD1 | c.1402C>T p.L468= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- GK2 | c.1419C>T p.S473= | Silent (SNP) | VAF 26/248 reads (10%) | catalogued as COSV62626225; called by muse, mutect2, varscan2
- GSX1 | c.642C>T p.G214= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as rs1302258904, COSV57232477; called by muse, mutect2, varscan2
- HAPLN2 | c.75A>G p.Q25= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs988403397; called by muse, mutect2, varscan2
- HARS2 | c.534C>T p.D178= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs1266947372, COSV51227540; called by muse, mutect2, varscan2
- HDAC7 | c.741A>C p.T247= (on ENST00000427332; = p.T286= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- KLHL10 | c.402A>T p.S134= | Silent (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- MMRN1 | c.3147G>A p.P1049= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs1278343393, COSV53338942, COSV53339823; called by muse, mutect2, varscan2
- MOSPD3 | c.624T>A p.P208= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- OBSCN | c.22767T>C p.I7589= | Silent (SNP) | VAF 75/190 reads (39%) | catalogued as COSV100800438; called by muse, mutect2, varscan2
- OR56A3 | c.480T>C p.T160= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV61568806; called by muse, mutect2, varscan2
- OR5L2 | c.432G>A p.L144= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as COSV101004303; called by muse, mutect2, varscan2
- PKHD1 | c.4038C>T p.N1346= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs147584295; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PPFIA1 | c.3594G>A p.R1198= | Silent (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- PRR19 | c.300C>T p.P100= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- RFC2 | c.885C>T p.I295= (on ENST00000055077 / NM_181471.3; = p.I261= on NM_002914.4) | Silent (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- SHANK2 | c.3003C>T p.Y1001= | Silent (SNP) | VAF 72/300 reads (24%) | catalogued as rs1202724625; called by muse, mutect2, varscan2
- SKIV2L | c.621A>G p.G207= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- SON | c.3282G>A p.S1094= | Silent (SNP) | VAF 70/306 reads (23%) | catalogued as rs536204949, COSV51666052; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRRM4 | c.855C>T p.Y285= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs201517536, COSV57408658; called by muse, mutect2, varscan2
- TMEM44 | c.1011A>G p.Q337= (on ENST00000392432 / NM_001166305.2; = p.Q290= on NM_138399.5) | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- USP20 | c.2199C>T p.T733= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs757777838; called by mutect2, varscan2
- ZGRF1 | c.4269A>G p.P1423= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs748122325; called by muse, mutect2, varscan2
- ZNF835 | c.516C>A p.G172= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- ASIC2 | c.556-179367C>G | Intron (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- PITPNC1 | c.683-5506A>G | Intron (SNP) | VAF 24/126 reads (19%) | catalogued as COSV55455657; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+651A>G | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
